Somatic mutation profile of tumor specimen 0DQ55L from CCDI case PBCBXJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 17.3 years (6,308 days).
Specimen 0DQ55L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33f96c44-42ac-42e3-bfa1-a6e878130a8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ55S (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/962c2c42-64d3-4550-a725-d23c1a97f226

The open-access MAF lists 30 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, Intron 4, 3'UTR 2, 5'UTR 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMPER | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 70/234 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1043861409, COSV51814238; called by muse, mutect2, varscan2
- CHST1 | c.917C>A p.A306D | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV57325007; called by muse, mutect2, varscan2
- FAM133A | c.566C>G p.P189R | Missense Mutation (SNP) | VAF 23/355 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59075717, COSV59075955; called by muse, mutect2
- KRT38 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 27/267 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs767626446, COSV55846793; called by muse, mutect2, varscan2
- MYO1F | c.231G>A p.A77= | Splice Region (SNP) | VAF 75/367 reads (20%) | catalogued as rs774761610, COSV57795311; called by muse, mutect2, varscan2
- SHOC1 | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 60/240 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as rs960070860; called by muse, mutect2, varscan2
- SLC39A4 | c.423C>A p.S141R (on ENST00000301305 / NM_001374839.1; = p.S116R on NM_017767.3) | Missense Mutation (SNP) | VAF 211/542 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as rs782392438; called by muse, mutect2, varscan2
- TDRD6 | c.5966C>T p.S1989L | Missense Mutation (SNP) | VAF 73/394 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as rs150855637; called by muse, mutect2, varscan2
- ARFGEF1 | c.3473C>G p.T1158R | Missense Mutation (SNP) | VAF 64/379 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CDIN1 | c.544+2dup p.X182_splice (on ENST00000437989; = p.X84_splice on NM_032499.6 and 1 other RefSeq transcript) | Splice Site (INS) | VAF 76/392 reads (19%) | called by mutect2, varscan2
- EPRS1 | c.2542G>C p.A848P | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.633); called by muse, varscan2
- FAM133A | c.565C>G p.P189A | Missense Mutation (SNP) | VAF 23/347 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2
- FSD2 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 96/374 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- LRP10 | c.626C>T p.T209I | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- OR52J3 | c.560C>G p.A187G | Missense Mutation (SNP) | VAF 97/318 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- PIK3CA | c.1896A>C p.L632F | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIGLEC5 | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 55/645 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.052); called by muse, mutect2
- ACTBL2 | c.81C>A p.A27= | Silent (SNP) | VAF 247/483 reads (51%) | catalogued as COSV101379445; called by muse, mutect2, varscan2
- KLHL21 | c.387G>C p.L129= | Silent (SNP) | VAF 51/151 reads (34%) | called by muse, mutect2, varscan2
- LRP2 | c.10803C>T p.C3601= | Silent (SNP) | VAF 285/527 reads (54%) | catalogued as rs370876114; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYF5 | c.273C>T p.R91= | Silent (SNP) | VAF 26/440 reads (6%) | catalogued as COSV57355011; called by muse, mutect2
- PLPP3 | c.849G>A p.T283= | Silent (SNP) | VAF 110/560 reads (20%) | catalogued as rs773818825; called by muse, mutect2, varscan2
- RASA3 | c.501C>T p.Y167= | Silent (SNP) | VAF 115/519 reads (22%) | catalogued as rs200944524, COSV61874485; called by muse, mutect2, varscan2
- ABHD6 | c.*99G>A | 3'UTR (SNP) | VAF 16/27 reads (59%) | catalogued as rs893511705; called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 12/99 reads (12%) | called by muse, varscan2
- FRAS1 | c.5856+113A>T | Intron (SNP) | VAF 12/78 reads (15%) | called by muse, varscan2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 8/68 reads (12%) | called by muse, varscan2
- MED23 | c.2779-34G>T | Intron (SNP) | VAF 11/112 reads (10%) | called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 13/100 reads (13%) | called by muse, varscan2
- WDR36 | c.*41G>A | 3'UTR (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
